Gene-level copy-number profile of tumor specimen TCGA-D5-6536-01A from TCGA case TCGA-D5-6536, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.6 years (26,890 days).
Specimen TCGA-D5-6536-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.180e6864-5288-4a06-9227-81c87addda99.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D5-6536-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a36b9285-e500-4b2a-be1a-70a2e14f633d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 9,785; copy number 3: 4,904; copy number 4: 37,954; copy number 5: 96; copy number 6: 4,232; copy number 7: 407; copy number 8: 691; copy number 9: 1,695; copy number 15: 54.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D5-6536-01A-11D-1717-01): tumor purity 0.74, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,749 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,754,216–40,257,967, 53 genes, copy number 15: AL354702.1, RRAGC, AL139260.2, AL139260.1, MYCBP, AL139260.3, GJA9, RHBDL2, RNU6-605P, Y_RNA, EIF1P2, AKIRIN1, NDUFS5, MACF1, RNU6-608P, RNA5SP44, AL442071.2, AL442071.1, HSPE1P8, BMP8A, OXCT2P1, PPIEL, PABPC4, PABPC4-AS1, SNORA55, HEYL, AL035404.2, NT5C1A, HPCAL4, PPIE, AL035404.1, RNU7-121P, BMP8B, OXCT2, BMP8B-AS1, AL033527.2, AL033527.1, AL033527.3, LINC02811, TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1, PPT1, OAZ1P1, RLF, RNU6-1237P, TMCO2, AL050341.2.
- chr1:40,262,672–40,262,984, 1 gene, copy number 15: AL050341.1.
- chr1:149,782,671–214,871,716, 1,637 genes, copy number 9 (broad region; genes not listed).
- chr1:237,862,175–241,595,642, 58 genes, copy number 9: AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1, MIR3123, AL592076.1, AL359764.1, AL359764.2, AL359764.3, FH, KMO.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
